Somatic mutation profile of tumor specimen TCGA-06-0213-01A (aliquot TCGA-06-0213-01A-01D-1491-08) from TCGA case TCGA-06-0213, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 55.1 years (20,134 days).
Specimen TCGA-06-0213-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4462da8e-d43a-492b-b9e8-557d4f5fe33c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0213-10A (Blood Derived Normal), aliquot TCGA-06-0213-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27339583-7def-4e33-a49e-f1fb4708f427

The open-access MAF lists 65 somatic variants for this specimen: 44 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 17, Nonsense Mutation 4, RNA 3, In Frame Del 1, Splice Site 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 36/101 reads (36%) | hotspot (GDC flag); catalogued as rs121909231, CM971278, COSV64288687, COSV64297951; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1960G>C p.V654L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.136); catalogued as rs483352690, CM034902, CM045967, CS050405, CS081965, CS083261, COSV57303318, COSV57309017, COSV57322012; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACP6 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100984282, COSV65076935; called by muse, mutect2, varscan2
- ARMCX2 | c.1793A>C p.Y598S | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as COSV57530199; called by muse, mutect2, varscan2
- CHSY3 | c.889C>G p.L297V | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.165); catalogued as COSV59277859; called by muse, mutect2, varscan2
- COL24A1 | c.3724_3726del p.Q1242del | In Frame Del (DEL) | VAF 99/327 reads (30%) | catalogued as rs1258399866; called by pindel, varscan2
- COL8A2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV57441937; called by muse, mutect2, varscan2
- CTTNBP2 | c.1231C>A p.Q411K | Missense Mutation (SNP) | VAF 95/493 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV50404392, COSV99354801; called by muse, mutect2, varscan2
- CX3CL1 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as rs777198174, COSV50055933; called by muse, mutect2, varscan2
- DCN | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 71/229 reads (31%) | catalogued as COSV50007217; called by muse, mutect2, varscan2
- DTX3L | c.2123A>G p.H708R | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780860986, COSV56144275; called by muse, mutect2, varscan2
- FGD5 | c.3497G>A p.R1166H | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs536923009, COSV53243551; called by muse, mutect2, varscan2
- FLG | c.11842G>T p.G3948C | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV64242392; called by muse, mutect2, varscan2
- FSTL5 | c.461A>G p.D154G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.628); catalogued as COSV60197386; called by muse, mutect2, varscan2
- GALNT17 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen probably damaging (0.959); catalogued as rs746859541, COSV61160500; called by muse, mutect2, varscan2
- GALT | c.687+1G>A p.X229_splice | Splice Site (SNP) | VAF 12/159 reads (8%) | catalogued as COSV66592962; called by muse, mutect2
- GLYATL1 | c.901C>T p.P301S (on ENST00000317391 / NM_001354699.1; = p.P332S on NM_080661.4) | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.025); catalogued as COSV55607632; called by muse, mutect2, varscan2
- GRIA3 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV52061295; called by muse, mutect2, varscan2
- ITGB4 | c.3310G>A p.D1104N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV52326441; called by muse, mutect2, varscan2
- LHX8 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53956959; called by muse, mutect2, varscan2
- MCOLN2 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 87/254 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV52295927; called by muse, mutect2, varscan2
- MPP7 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200656300; called by muse, mutect2, varscan2
- MRAP2 | c.504C>A p.N168K | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57632546; called by muse, mutect2, varscan2
- NBEAL1 | c.6188A>G p.K2063R | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV68916109; called by muse, mutect2, varscan2
- NPRL3 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67853011; called by muse, mutect2
- NPSR1 | c.27C>A p.S9R | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.134); catalogued as COSV100706037, COSV62200987; called by muse, mutect2, varscan2
- OR5AC2 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs200290395, COSV62279564; called by muse, mutect2, varscan2
- POLR3B | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57279480; called by muse, mutect2, varscan2
- PSORS1C1 | c.139T>C p.C47R | Missense Mutation (SNP) | VAF 82/258 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52535657; called by muse, mutect2, varscan2
- RBBP5 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as COSV52704685; called by muse, mutect2, varscan2
- RELN | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 51/235 reads (22%) | catalogued as COSV59004278, COSV59015620; called by muse, mutect2, varscan2
- RIMBP2 | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as rs753433895, COSV55464885, COSV55487366; called by muse, mutect2, varscan2
- RNF128 | c.1202A>G p.D401G (on ENST00000255499 / NM_194463.2; = p.D375G on NM_024539.3) | Missense Mutation (SNP) | VAF 119/356 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1177397132, COSV55251195; called by muse, mutect2, varscan2
- SCN9A | c.5705G>C p.R1902P (on ENST00000303354; = p.R1891P on NM_002977.3) | Missense Mutation (SNP) | VAF 54/184 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV57611089; called by muse, mutect2, varscan2
- SH2D1B | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs747946218, COSV63392264; called by muse, mutect2, varscan2
- SIRPA | c.328A>G p.N110D | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as COSV61538940; called by muse, varscan2
- SLIT3 | c.2230C>T p.R744C | Missense Mutation (SNP) | VAF 76/230 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs772402436, COSV60609781, COSV60620013; called by muse, mutect2, varscan2
- SRPRA | c.511G>C p.G171R | Missense Mutation (SNP) | VAF 123/455 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.173); catalogued as COSV55006789; called by muse, mutect2, varscan2
- SSC4D | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.206); catalogued as rs761028731, COSV51882493; called by muse, mutect2, varscan2
- TAF1 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV52114155; called by muse, mutect2, varscan2
- TDRD7 | c.2723C>G p.S908* | Nonsense Mutation (SNP) | VAF 33/123 reads (27%) | catalogued as COSV62429568, COSV62430862; called by muse, mutect2, varscan2
- TMC3 | c.3211C>T p.P1071S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as rs1407022287, COSV63923290; called by muse, mutect2, varscan2
- TTC12 | c.1663G>A p.V555I | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV59098002; called by muse, mutect2, varscan2
- ATRX | c.5480del p.L1827Cfs*9 | Frame Shift Del (DEL) | VAF 39/152 reads (26%) | called by mutect2, pindel, varscan2
- B3GNT8 | c.138G>A p.T46= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs777773985, COSV54197293; called by muse, mutect2, varscan2
- CD163L1 | c.150G>A p.L50= | Silent (SNP) | VAF 55/190 reads (29%) | catalogued as COSV58016981; called by muse, varscan2
- COL3A1 | c.2802G>A p.S934= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs113870310, COSV58586035; ClinVar: likely benign; called by muse, mutect2, varscan2
- CYP4A11 | c.165C>T p.P55= | Silent (SNP) | VAF 65/169 reads (38%) | catalogued as COSV60223796, COSV60225318; called by muse, mutect2, varscan2
- FAT3 | c.6138A>G p.E2046= | Silent (SNP) | VAF 4/94 reads (4%) | catalogued as rs1222602381, COSV53116203; called by muse, mutect2
- JAG2 | c.1149C>T p.A383= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV59309412; called by muse, mutect2, varscan2
- KNDC1 | c.5145C>G p.S1715= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV58837805; called by muse, mutect2, varscan2
- KRT7 | c.1371C>A p.I457= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV57766377, COSV57767351; called by muse, mutect2, varscan2
- LAMP2 | c.783C>A p.S261= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV52353239; called by muse, mutect2, varscan2
- MYOC | c.435C>A p.L145= | Silent (SNP) | VAF 59/329 reads (18%) | catalogued as COSV50675121; called by muse, mutect2, varscan2
- OR5L2 | c.300A>G p.Q100= | Silent (SNP) | VAF 91/306 reads (30%) | catalogued as rs758911283, COSV65724144; called by muse, mutect2, varscan2
- PACRG | c.267G>A p.S89= | Silent (SNP) | VAF 98/283 reads (35%) | catalogued as rs759185651, COSV61305720; called by muse, mutect2, varscan2
- SCN4A | c.5076G>A p.G1692= | Silent (SNP) | VAF 40/139 reads (29%) | catalogued as COSV71127047; called by muse, mutect2, varscan2
- THOC2 | c.2694C>T p.S898= | Silent (SNP) | VAF 47/148 reads (32%) | catalogued as COSV55546486; called by muse, mutect2, varscan2
- TNFSF15 | c.507C>T p.G169= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV65010366; called by muse, mutect2, varscan2
- TRAPPC12 | c.630C>T p.F210= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs771806325, COSV60847805; called by muse, mutect2, varscan2
- ULBP1 | c.642C>T p.A214= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV57664262; called by muse, mutect2, varscan2
- DNM1P46 | n.148G>A | RNA (SNP) | VAF 23/76 reads (30%) | called by mutect2, varscan2
- KIAA1549L | c.1882+14T>C | Intron (SNP) | VAF 30/94 reads (32%) | catalogued as COSV55778460; called by muse, mutect2
- MALAT1 | n.107A>G | RNA (SNP) | VAF 41/156 reads (26%) | called by muse, mutect2, varscan2
- XIST | n.9806C>T | RNA (SNP) | VAF 35/154 reads (23%) | catalogued as rs1049626400; called by muse, mutect2, varscan2
